Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01T, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01T-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

This is a poorly differentiated adenocarcinoma of the sigmoid colon with a histopathological grade G3 differentiation, with ulceration and erosions of the inner tumor surface, with fine foci of necrosis, with peritumorous chronic recurrent inflammation, with tumor infiltration in the layers of the sigmoid colon wall as far as the pericolic fatty connective tissue, with carcinomatous lymphangiosis, with a regional lymph node metastasis (1/15) and tumor-free overview sections from the resection margins.

According to these prepared sections, the tumor spread of the sigmoid colon carcinoma corresponds to the tumor stage pT3, pN1 (1/15), MX, L1, R0

10+

ICD-0-3

Adenocarcinoma, Nos 8140/3

Site: sigmoid colon C18.7 p 3/30/11

Reviewed Initials	5/10/11	

Source: NCI Genomic Data Commons file 10afe417-bf56-4de2-99bf-6936f82ed8c8 (TCGA-AA-A01T.7DBAA2D8-44FA-4726-94DC-3AFCFBFF15D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).